TCGA case TCGA-EP-A3JL — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a196a937-b17d-4d4a-965b-8af0f4f41367

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 76.3 years (27,886 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 303 days; Child pugh classification: A.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the other ill-defined sites (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 97 days; Disease response: Tumor Free.
- Days to follow up: 303 days; Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Albumin 4.1 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.2; Blood test normal range upper: 4.8].
- Platelets 149 (unit not recorded by GDC) [Blood test normal range lower: 130; Blood test normal range upper: 386].
- Alpha Fetoprotein 13 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 9].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 168 cm; BMI: 25.9.
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EP-A3JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 570 mg.
  Slide TCGA-EP-A3JL-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EP-A3JL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EP-A3JL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Surgical procedure other: Laparoscopic Partial Hepatectomy in segment 4B and 5, Laproscopic Cholecystectomy, Ultrasound guided Radiofrequency Ablation of 4cm for a 2.2cm lesion between the Left pportal vein and middle hepatic vein.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Back.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a prior tumor in the back. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 303 days; disease-specific survival: no event (censored), 303 days; progression-free interval: no event (censored), 303 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EP-A3JL-01A-11D-A20V-01): tumor purity 0.53, ploidy 2.52, whole-genome doublings 0.
